Somatic mutation profile of tumor specimen TCGA-FP-7829-01A (aliquot TCGA-FP-7829-01A-11D-2053-08) from TCGA case TCGA-FP-7829, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 69.9 years (25,534 days).
Specimen TCGA-FP-7829-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e1559a9c-ba33-4a2f-ab6b-c4f6e14777a0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FP-7829-10A (Blood Derived Normal), aliquot TCGA-FP-7829-10A-01D-2053-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ad34824b-aa58-484f-a307-5582a8825edb

The open-access MAF lists 269 somatic variants for this specimen: 195 protein-altering or splice-affecting, 67 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 170, Silent 67, Nonsense Mutation 12, Splice Region 4, Intron 4, Frame Shift Ins 3, Frame Shift Del 3, Splice Site 2, RNA 1, 3'Flank 1, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMAD4 | c.1067C>T p.P356L | Missense Mutation (SNP) | VAF 19/30 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61685209, COSV61685537, COSV61689602; called by muse, mutect2, varscan2
- TP53 | c.527G>T p.C176F | Missense Mutation (SNP) | VAF 37/53 reads (70%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACAN | c.1969C>T p.P657S | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.068); catalogued as COSV104419288, COSV61366217; called by muse, varscan2
- ACP4 | c.19T>G p.W7G | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs771413438, COSV54518184; called by muse, mutect2, varscan2
- ADAM23 | c.2132G>T p.G711V | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52209180, COSV52224553; called by muse, mutect2, varscan2
- ADAMTS18 | c.2749A>C p.T917P | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV51420618; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1987G>A p.G663S | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54460910; called by muse, mutect2, varscan2
- APLP2 | c.1969G>A p.E657K | Missense Mutation (SNP) | VAF 54/71 reads (76%) | SIFT tolerated (0.15); PolyPhen benign (0.225); catalogued as rs776057355, COSV53843055; called by muse, mutect2, varscan2
- ARCN1 | c.553G>A p.G185R | Missense Mutation (SNP) | VAF 76/98 reads (78%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as rs782373336, COSV50614946; called by muse, varscan2
- ARFGEF2 | c.2231G>A p.R744Q | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777290585, COSV64214158; called by muse, mutect2, varscan2
- ASPM | c.3193C>T p.Q1065* | Nonsense Mutation (SNP) | VAF 6/17 reads (35%) | catalogued as COSV54135338; called by muse, mutect2, varscan2
- ATP10A | c.3915G>T p.Q1305H | Missense Mutation (SNP) | VAF 52/102 reads (51%) | SIFT tolerated (0.32); PolyPhen benign (0.014); catalogued as COSV100790800, COSV63521292; called by muse, mutect2, varscan2
- ATP1B2 | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as COSV51516276; called by muse, mutect2, varscan2
- BEND5 | c.737T>G p.L246R | Missense Mutation (SNP) | VAF 48/78 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV65718197; called by muse, mutect2
- BEST1 | c.1162G>C p.G388R | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.64); catalogued as COSV56446209; called by muse, mutect2, varscan2
- BORCS8-MEF2B | c.50C>T p.T17M | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.76); catalogued as rs766141253, COSV50767126; called by muse, mutect2, varscan2
- C21orf62 | c.482G>A p.W161* | Nonsense Mutation (SNP) | VAF 11/44 reads (25%) | catalogued as COSV66672461; called by muse, mutect2, varscan2
- CACNA1H | c.3691C>T p.R1231C | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs781510850, COSV61999160; called by muse, mutect2, varscan2
- CASS4 | c.2071C>T p.H691Y | Missense Mutation (SNP) | VAF 47/219 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.14); catalogued as COSV64387790, COSV64388208; called by muse, mutect2, varscan2
- CEP170 | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63733387; called by muse, mutect2, varscan2
- CFAP46 | c.190G>A p.V64M | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.788); catalogued as rs376888644; called by muse, mutect2, varscan2
- CHAT | c.1208G>T p.R403M | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0.437); catalogued as COSV100340451, COSV60330022; called by muse, mutect2, varscan2
- CILP2 | c.1232A>G p.D411G | Missense Mutation (SNP) | VAF 56/172 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.488); catalogued as COSV52278561; called by muse, mutect2, varscan2
- CLDN17 | c.498C>A p.F166L | Missense Mutation (SNP) | VAF 24/34 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV54524099; called by muse, mutect2, varscan2
- CLEC4E | c.489C>T p.S163= | Splice Region (SNP) | VAF 10/44 reads (23%) | catalogued as COSV55226780; called by muse, mutect2, varscan2
- CLIC4 | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 51/134 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.883); catalogued as rs145958058; called by muse, mutect2, varscan2
- CNTN5 | c.3132A>C p.E1044D | Missense Mutation (SNP) | VAF 67/84 reads (80%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV54340707; called by muse, mutect2, varscan2
- CNTN6 | c.2648A>C p.N883T | Missense Mutation (SNP) | VAF 71/112 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV63183344; called by muse, mutect2, varscan2
- COL4A2 | c.3994G>A p.G1332R | Missense Mutation (SNP) | VAF 36/52 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762275000, COSV64629651; called by muse, mutect2, varscan2
- COL5A2 | c.4336C>A p.L1446I | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.397); catalogued as COSV66412868; called by muse, mutect2, varscan2
- COL6A3 | c.9336C>A p.C3112* | Nonsense Mutation (SNP) | VAF 12/50 reads (24%) | catalogued as COSV55101678; called by muse, mutect2, varscan2
- CPN1 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.484); catalogued as COSV64942642; called by muse, mutect2, varscan2
- DAPK1 | c.1746T>A p.H582Q | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63790233; called by muse, mutect2, varscan2
- DCLK1 | c.347A>G p.K116R | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.082); catalogued as rs764457570, COSV55201161, COSV55205427; called by muse, mutect2, varscan2
- DCT | c.248G>A p.R83H | Missense Mutation (SNP) | VAF 56/168 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374657624; called by muse, mutect2, varscan2
- DENND1C | c.570G>A p.R190= | Splice Region (SNP) | VAF 10/63 reads (16%) | catalogued as rs1167412082, COSV67374569; called by muse, mutect2, varscan2
- DOCK7 | c.5982A>C p.E1994D (on ENST00000635253 / NM_001367561.1; = p.E1963D on NM_033407.3) | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99225436; called by muse, mutect2, varscan2
- DSG3 | c.211G>T p.A71S | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57128390; called by muse, mutect2, varscan2
- DUOX2 | c.4433G>A p.R1478Q | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.393); catalogued as rs759342749, COSV66532147; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DVL3 | c.514G>A p.G172S | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.034); catalogued as COSV57457577; called by muse, mutect2, varscan2
- EBF3 | c.703C>T p.H235Y | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.399); catalogued as COSV62479209; called by muse, mutect2, varscan2
- EDNRB | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.429); catalogued as COSV100526896; called by muse, mutect2, varscan2
- EGFLAM | c.1862C>A p.A621E | Missense Mutation (SNP) | VAF 33/189 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.629); catalogued as COSV59312192; called by muse, mutect2, varscan2
- EGFR | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.129); catalogued as rs758748662, COSV51785554, COSV51829933; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ELAVL2 | c.775G>A p.G259R | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0.062); catalogued as COSV56366595, COSV56368908; called by muse, mutect2, varscan2
- ELAVL4 | c.27G>T p.E9D | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.031); catalogued as rs750517639, COSV63918295; called by muse, mutect2, varscan2
- ELAVL4 | c.317C>G p.T106S | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.014); catalogued as COSV100836641, COSV63915128, COSV63918303; called by muse, mutect2, varscan2
- EPYC | c.261A>T p.E87D | Missense Mutation (SNP) | VAF 35/53 reads (66%) | SIFT tolerated (0.48); PolyPhen benign (0.196); catalogued as COSV53801225; called by muse, mutect2, varscan2
- ERICH3 | c.776G>A p.R259H | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.202); catalogued as rs372763080; called by muse, mutect2, varscan2
- EYS | c.1457C>A p.A486E | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as COSV60977941, COSV60980480; called by muse, mutect2, varscan2
- FAM20B | c.462C>T p.D154= | Splice Region (SNP) | VAF 75/134 reads (56%) | catalogued as COSV55381707; called by muse, mutect2, varscan2
- FAM71A | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201801823; called by muse, mutect2, varscan2
- FAT1 | c.2468T>A p.L823* | Nonsense Mutation (SNP) | VAF 57/129 reads (44%) | catalogued as COSV71675371; called by muse, mutect2, varscan2
- FAT2 | c.10383dup p.Y3462Lfs*26 | Frame Shift Ins (INS) | VAF 20/66 reads (30%) | catalogued as rs747011618; called by mutect2, varscan2
- FBXL7 | c.937G>A p.D313N | Missense Mutation (SNP) | VAF 34/48 reads (71%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV61650133; called by muse, mutect2, varscan2
- FBXO46 | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV58349404, COSV58350117; called by muse, mutect2, varscan2
- FEZF1 | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 15/18 reads (83%) | SIFT tolerated (0.35); PolyPhen benign (0.297); catalogued as rs777966600, COSV58659358; called by muse, mutect2, varscan2
- FHOD3 | c.1063C>T p.R355W | Missense Mutation (SNP) | VAF 35/50 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as rs960627486, COSV57173045, COSV99942301; called by muse, mutect2, varscan2
- FLG | c.5281C>T p.R1761C | Missense Mutation (SNP) | VAF 117/381 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs149721675; called by muse, mutect2, varscan2
- FLYWCH1 | c.830G>A p.C277Y (on ENST00000253928 / NM_001308068.2; = p.C276Y on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54148608; called by muse, mutect2, varscan2
- FMN2 | c.1340C>T p.P447L | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs1248438934, COSV60420273, COSV60436202; called by muse, mutect2, varscan2
- GABRA1 | c.1148A>C p.D383A | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.338); catalogued as COSV50113444; called by muse, mutect2, varscan2
- GAL3ST4 | c.1089C>A p.N363K | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); catalogued as COSV57587674; called by muse, mutect2, varscan2
- GDF5 | c.665A>G p.Y222C | Missense Mutation (SNP) | VAF 57/303 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65502752; called by muse, mutect2, varscan2
- GLP2R | c.965G>A p.R322H | Missense Mutation (SNP) | VAF 91/222 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs753312498, COSV52327885; called by muse, mutect2, varscan2
- GNG7 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as rs750562679, COSV66287460; called by muse, mutect2, varscan2
- GPAA1 | c.776G>T p.C259F | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.299); catalogued as rs782688828, COSV60156269; called by muse, mutect2, varscan2
- GPR171 | c.712C>A p.P238T | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56390517; called by muse, mutect2, varscan2
- GRIK3 | c.1744G>T p.V582F | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66136375, COSV66144296; called by muse, mutect2, varscan2
- HELQ | c.2446A>T p.T816S | Missense Mutation (SNP) | VAF 61/68 reads (90%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV55026758; called by muse, mutect2, varscan2
- HELZ | c.5491A>T p.I1831L | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV62380015; called by muse, mutect2, varscan2
- IMPG2 | c.916G>A p.D306N | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.179); catalogued as COSV51983127, COSV51985880; called by muse, mutect2, varscan2
- INTS2 | c.2737G>A p.V913I | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV52155434; called by muse, mutect2, varscan2
- IRAK2 | c.1331C>T p.T444M | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.039); catalogued as rs1399709908, COSV56531866; called by muse, varscan2
- IRX1 | c.526A>G p.T176A | Missense Mutation (SNP) | VAF 30/187 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV57361442; called by muse, mutect2, varscan2
- JAKMIP1 | c.1501G>A p.A501T | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1351104472, COSV51540819; called by muse, mutect2, varscan2
- KDM4B | c.1463C>T p.P488L | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT tolerated (0.07); PolyPhen benign (0.228); catalogued as rs756397144, COSV50243081, COSV99345667; called by muse, mutect2, varscan2
- KIF2B | c.1510C>T p.R504W | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757000396, COSV52127134; called by muse, mutect2, varscan2
- KLB | c.1840G>A p.A614T | Missense Mutation (SNP) | VAF 46/87 reads (53%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV57302120; called by muse, mutect2, varscan2
- KLF8 | c.664T>C p.S222P | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.278); catalogued as COSV63848472; called by muse, mutect2, varscan2
- L3MBTL4 | c.1445-2A>G p.X482_splice | Splice Site (SNP) | VAF 52/126 reads (41%) | catalogued as COSV53133746; called by muse, mutect2, varscan2
- LATS1 | c.1100C>T p.T367I | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV53596660, COSV53603795; called by muse, mutect2, varscan2
- LGI3 | c.1473G>T p.Q491H | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV60444177; called by muse, mutect2, varscan2
- LIG1 | c.1669C>T p.R557C | Missense Mutation (SNP) | VAF 83/303 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs372831646; called by muse, mutect2, varscan2
- LINGO2 | c.1172G>A p.R391K | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58061923, COSV58062553; called by muse, mutect2, varscan2
- LRP1B | c.52G>T p.A18S | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.097); catalogued as COSV67256181; called by muse, mutect2, varscan2
- LRRTM3 | c.676C>A p.P226T | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63665904, COSV63669767; called by muse, mutect2, varscan2
- MAP2 | c.3635T>C p.I1212T | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.089); catalogued as COSV52302335; called by muse, mutect2, varscan2
- MEI1 | c.3385G>A p.E1129K | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV55905745; called by muse, mutect2, varscan2
- METTL2A | c.703G>T p.A235S | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV61044014, COSV61045536; called by muse, varscan2
- MPP4 | c.1307C>T p.S436F | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV59633265; called by muse, varscan2
- MRPS33 | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 54/80 reads (68%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs753508371, COSV61341586; called by muse, mutect2, varscan2
- MTF1 | c.1142C>T p.T381M | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.253); catalogued as rs763643120, COSV65989306; called by muse, mutect2, varscan2
- MTSS1 | c.2132A>G p.Q711R | Missense Mutation (SNP) | VAF 110/481 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.028); catalogued as rs1381186243, COSV52675748; called by muse, mutect2, varscan2
- MUC16 | c.38219A>T p.K12740M | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV67481996; called by muse, mutect2, varscan2
- MUC5B | c.14552C>T p.P4851L | Missense Mutation (SNP) | VAF 34/167 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs201730803; called by muse, mutect2, varscan2
- MXRA5 | c.7222G>T p.A2408S | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV54235179, COSV54244508; called by muse, mutect2, varscan2
- MYH10 | c.5462C>T p.A1821V | Missense Mutation (SNP) | VAF 29/152 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as COSV52607378; called by muse, mutect2, varscan2
- MYH13 | c.462C>A p.H154Q | Missense Mutation (SNP) | VAF 109/316 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV52837433; called by muse, mutect2, varscan2
- MYH4 | c.805T>C p.Y269H | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55123448; called by muse, mutect2, varscan2
- MYOM2 | c.2888A>T p.D963V | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.462); catalogued as COSV50748437; called by muse, mutect2, varscan2
- NEBL | c.2241G>A p.S747= | Splice Region (SNP) | VAF 20/37 reads (54%) | catalogued as rs377702958, COSV65804872; called by muse, mutect2, varscan2
- NEURL2 | c.230G>A p.W77* | Nonsense Mutation (SNP) | VAF 28/56 reads (50%) | catalogued as COSV51944014; called by muse, mutect2, varscan2
- NOS3 | c.1835G>A p.R612H | Missense Mutation (SNP) | VAF 62/79 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs930680433, COSV52486606; called by muse, mutect2, varscan2
- NPAP1 | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.049); catalogued as rs767660483, COSV100275953, COSV61509798; called by muse, mutect2, varscan2
- NPAS3 | c.1577G>A p.R526H (on ENST00000356141 / NM_001164749.2; = p.R494H on NM_022123.3) | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.145); catalogued as rs779310871, COSV60851824; called by muse, mutect2, varscan2
- NRXN3 | c.2852A>G p.D951G (on ENST00000335750 / NM_001330195.2; = p.D578G on NM_004796.6) | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59786133; called by muse, mutect2, varscan2
- NSD1 | c.2927C>A p.A976D | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.013); catalogued as COSV61781367; called by muse, mutect2, varscan2
- NWD1 | c.895C>T p.R299C | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.799); catalogued as rs775286731, COSV100343969, COSV60348208; called by muse, mutect2, varscan2
- OR1L3 | c.94C>A p.L32I | Missense Mutation (SNP) | VAF 38/139 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.237); catalogued as COSV59170392; called by muse, mutect2, varscan2
- OR2C3 | c.712G>T p.A238S | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV63575835; called by muse, mutect2, varscan2
- OR2G6 | c.728C>A p.S243Y | Missense Mutation (SNP) | VAF 44/69 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100598262, COSV58575394; called by muse, mutect2, varscan2
- OR2T6 | c.370G>A p.V124M | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.298); catalogued as rs201925418, COSV63216883; called by muse, mutect2, varscan2
- OR52H1 | c.562C>A p.Q188K (on ENST00000322653; = p.Q194K on NM_001005289.1) | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV59506027; called by muse, mutect2, varscan2
- OR56A1 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as rs776414665, COSV57362957; called by muse, mutect2, varscan2
- OR6K3 | c.315G>T p.K105N (on ENST00000368146; = p.K89N on NM_001005327.2) | Missense Mutation (SNP) | VAF 124/198 reads (63%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV100933869, COSV63746194; called by muse, mutect2, varscan2
- OR6Y1 | c.882T>G p.I294M | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747810419, COSV56930607; called by muse, mutect2, varscan2
- OR7G1 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs757519729, COSV53318498; called by muse, mutect2, varscan2
- OR8B3 | c.58C>A p.H20N | Missense Mutation (SNP) | VAF 114/128 reads (89%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV63541751, COSV63542079; called by muse, mutect2, varscan2
- PCDHA3 | c.1924G>A p.A642T | Missense Mutation (SNP) | VAF 58/109 reads (53%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.329); catalogued as COSV63540253; called by muse, mutect2, varscan2
- PCDHB12 | c.184C>T p.R62W | Missense Mutation (SNP) | VAF 56/129 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs782691165, COSV53396750; called by muse, mutect2, varscan2
- PCNX3 | c.5133G>C p.E1711D | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as COSV63139358; called by muse, mutect2, varscan2
- PDZD2 | c.6718C>A p.P2240T | Missense Mutation (SNP) | VAF 94/522 reads (18%) | SIFT tolerated (0.75); PolyPhen benign (0.212); catalogued as COSV56860149; called by muse, mutect2, varscan2
- PEX13 | c.1126G>T p.A376S | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.978); catalogued as COSV54371060; called by muse, mutect2, varscan2
- PHACTR4 | c.1340A>T p.E447V (on ENST00000373839 / NM_001350159.2; = p.E457V on NM_023923.4) | Missense Mutation (SNP) | VAF 62/166 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV65784828; called by muse, mutect2, varscan2
- PIK3R5 | c.26C>T p.T9M | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777086538, COSV52655561; called by muse, mutect2, varscan2
- PLCL1 | c.2890C>T p.Q964* | Nonsense Mutation (SNP) | VAF 44/109 reads (40%) | catalogued as COSV70856389; called by muse, mutect2, varscan2
- PLOD2 | c.1715C>G p.S572C | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV51467475; called by muse, mutect2, varscan2
- POLQ | c.7133T>C p.L2378P | Missense Mutation (SNP) | VAF 47/167 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.362); catalogued as COSV51758203; called by muse, mutect2, varscan2
- PPIP5K1 | c.4186G>A p.E1396K (on ENST00000396923; = p.E1371K on NM_014659.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/101 reads (51%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV55811354; called by muse, mutect2, varscan2
- PPP1R12B | c.242G>T p.G81V | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61121489; called by muse, mutect2, varscan2
- PPP6R1 | c.1723G>A p.E575K | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.145); catalogued as COSV69799194, COSV69800384; called by muse, mutect2, varscan2
- PRKCD | c.877C>A p.Q293K | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.67); PolyPhen benign (0.017); catalogued as COSV57850295; called by muse, mutect2, varscan2
- PYGL | c.373G>T p.E125* | Nonsense Mutation (SNP) | VAF 38/95 reads (40%) | catalogued as COSV53587750; called by muse, mutect2, varscan2
- QRSL1 | c.1316G>T p.R439I | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.213); catalogued as COSV64689237; called by muse, mutect2, varscan2
- RABEP1 | c.841C>A p.Q281K | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.952); catalogued as COSV52587246; called by muse, mutect2
- RASA1 | c.1549A>T p.K517* | Nonsense Mutation (SNP) | VAF 33/47 reads (70%) | catalogued as COSV57199553; called by muse, mutect2, varscan2
- RASA3 | c.1237G>A p.D413N | Missense Mutation (SNP) | VAF 58/83 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199766447, COSV61871329; called by muse, mutect2, varscan2
- RBFA | c.741G>T p.Q247H | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777683292, COSV51534786; called by muse, mutect2, varscan2
- RBM33 | c.1460C>T p.P487L | Missense Mutation (SNP) | VAF 77/106 reads (73%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.795); catalogued as rs774572485, COSV56635579; called by muse, mutect2, varscan2
- RDH8 | c.868G>A p.V290M (on ENST00000651512; = p.V270M on NM_015725.4) | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.039); catalogued as rs768558441, COSV50673907; called by muse, mutect2, varscan2
- RIN3 | c.1411G>C p.A471P | Missense Mutation (SNP) | VAF 69/145 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as COSV53653463, COSV53656781; called by muse, mutect2, varscan2
- RP1L1 | c.1652G>A p.R551Q | Missense Mutation (SNP) | VAF 96/191 reads (50%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs758393932, COSV66758516; called by muse, mutect2, varscan2
- SCARA3 | c.778C>T p.R260W | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs147727919; called by muse, mutect2, varscan2
- SKOR1 | c.2063G>T p.G688V | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV58248877; called by muse, mutect2, varscan2
- SLC17A5 | c.653G>T p.G218V | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV63288171; called by muse, mutect2, varscan2
- SLC23A3 | c.1717G>T p.D573Y (on ENST00000409878 / NM_001144889.2; = p.D456Y on NM_144712.5) | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.282); catalogued as rs1231894569, COSV99841287; called by muse, mutect2, varscan2
- SLC2A12 | c.864dup p.V289Cfs*26 | Frame Shift Ins (INS) | VAF 37/98 reads (38%) | catalogued as rs1163021209; called by mutect2, pindel, varscan2
- SLC38A6 | c.883A>G p.I295V | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs762517433, COSV50781072, COSV50784622; called by muse, mutect2, varscan2
- SLC66A3 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 60/124 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.704); catalogued as COSV54467893; called by muse, mutect2, varscan2
- SMG9 | c.752A>T p.N251I | Missense Mutation (SNP) | VAF 86/167 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV54215868; called by muse, mutect2, varscan2
- SNAI2 | c.155C>A p.A52E | Missense Mutation (SNP) | VAF 45/330 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.08); catalogued as COSV50079863; called by muse, mutect2, varscan2
- SNTG2 | c.848A>G p.N283S | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV57998846; called by muse, mutect2, varscan2
- SORBS3 | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs773982336, COSV53554181, COSV99531466; called by muse, mutect2, varscan2
- SORCS1 | c.2536G>A p.V846I | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.403); catalogued as rs756255470, COSV53891460; called by muse, mutect2, varscan2
- SOX1 | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV58379981; called by muse, mutect2, varscan2
- SRSF4 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 28/46 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV65695459, COSV65696012; called by muse, mutect2, varscan2
- SUSD4 | c.1310C>A p.S437Y | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV59555256, COSV99070035; called by muse, mutect2, varscan2
- TACC2 | c.2911G>T p.D971Y | Missense Mutation (SNP) | VAF 62/106 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); catalogued as rs1424310114, COSV57750334; called by muse, mutect2, varscan2
- TBC1D21 | c.212C>T p.T71M | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs760609916, COSV55996267; called by muse, mutect2, varscan2
- TCEAL6 | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs781796512, COSV65654001; called by muse, mutect2, varscan2
- TCF21 | c.234G>T p.Q78H | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as COSV52819033; called by muse, mutect2, varscan2
- TEX55 | c.610C>T p.R204* | Nonsense Mutation (SNP) | VAF 38/180 reads (21%) | catalogued as rs749756682, COSV55210194, COSV99817551; called by muse, mutect2, varscan2
- TIE1 | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.249); catalogued as COSV65250807; called by muse, mutect2, varscan2
- TKTL1 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 54/65 reads (83%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.029); catalogued as rs782095901, COSV54212538; called by muse, mutect2, varscan2
- TRIM72 | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 37/181 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.425); catalogued as rs374969194, COSV57251982; called by muse, mutect2, varscan2
- TRPS1 | c.2989C>T p.P997S (on ENST00000220888 / NM_001330599.2; = p.P1010S on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/196 reads (27%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.01); catalogued as COSV55254997, COSV99629474; called by muse, mutect2, varscan2
- TSHZ3 | c.1423G>A p.D475N | Missense Mutation (SNP) | VAF 97/200 reads (49%) | SIFT tolerated (0.24); PolyPhen benign (0.062); catalogued as rs1450365947, COSV53663468; called by muse, mutect2, varscan2
- UBE4A | c.2056G>A p.A686T (on ENST00000252108 / NM_001204077.2; = p.A693T on NM_004788.4) | Missense Mutation (SNP) | VAF 237/289 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs782356501, COSV52806176; called by muse, mutect2, varscan2
- UNC13C | c.1846C>A p.Q616K | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.003); catalogued as COSV52906371; called by muse, mutect2, varscan2
- UNC13C | c.2512C>G p.Q838E | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); catalogued as COSV52906390; called by muse, mutect2, varscan2
- USP3 | c.909-1G>A p.X303_splice | Splice Site (SNP) | VAF 25/80 reads (31%) | catalogued as COSV51429084; called by muse, mutect2, varscan2
- WIPI1 | c.1169C>A p.A390E | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0.013); catalogued as COSV50930989; called by muse, mutect2, varscan2
- XPO5 | c.63G>A p.M21I | Missense Mutation (SNP) | VAF 85/354 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.182); catalogued as COSV54833383, COSV54834226; called by muse, mutect2, varscan2
- XXYLT1 | c.826C>T p.R276W | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as rs780456426, COSV59986693; called by muse, mutect2, varscan2
- ZBBX | c.974A>C p.K325T | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56797017; called by muse, mutect2, varscan2
- ZFHX3 | c.7671G>T p.Q2557H | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs1162760672, COSV51729259, COSV99213282; called by muse, mutect2, varscan2
- ZFP28 | c.2296T>A p.F766I | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56737362; called by muse, mutect2, varscan2
- ZFPM2 | c.1331A>C p.K444T | Missense Mutation (SNP) | VAF 21/30 reads (70%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.626); catalogued as COSV65873847, COSV65875092; called by muse, mutect2, varscan2
- ZNF106 | c.2154A>C p.E718D | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT tolerated (0.42); PolyPhen benign (0.011); catalogued as COSV55520183; called by muse, mutect2, varscan2
- ZNF341 | c.352A>G p.I118V | Missense Mutation (SNP) | VAF 51/118 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.952); catalogued as rs1320107221, COSV61010430; called by muse, mutect2, varscan2
- ZNF429 | c.515C>A p.P172H | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT tolerated (0.29); PolyPhen benign (0.105); catalogued as rs868445050, COSV61917937; called by muse, mutect2
- ZNF880 | c.1087C>T p.R363* | Nonsense Mutation (SNP) | VAF 15/28 reads (54%) | catalogued as rs775220661, COSV69906696; called by muse, mutect2, varscan2
- ZP4 | c.1096C>T p.Q366* | Nonsense Mutation (SNP) | VAF 23/92 reads (25%) | catalogued as rs1433541197, COSV63912174; called by muse, mutect2, varscan2
- ZZEF1 | c.6545C>G p.T2182S | Missense Mutation (SNP) | VAF 100/244 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.162); catalogued as COSV67559328; called by muse, mutect2, varscan2
- ZZEF1 | c.5731G>A p.A1911T | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.484); catalogued as rs758252836, COSV67556220; called by muse, mutect2, varscan2
- ANKRD30A | c.3215del p.A1072Vfs*7 (on ENST00000611781; = p.A1016Vfs*7 on NM_052997.2) | Frame Shift Del (DEL) | VAF 20/64 reads (31%) | called by mutect2, pindel, varscan2
- CC2D1A | c.1979_1983dup p.V662Sfs*3 | Frame Shift Ins (INS) | VAF 29/55 reads (53%) | called by mutect2, pindel, varscan2
- IGLV2-18 | c.175C>A p.Q59K | Missense Mutation (SNP) | VAF 121/276 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- NUP62 | c.1259_1260del p.T420Nfs*8 | Frame Shift Del (DEL) | VAF 22/109 reads (20%) | called by mutect2, pindel, varscan2
- PRAMEF15 | c.1192G>T p.E398* | Nonsense Mutation (SNP) | VAF 45/332 reads (14%) | called by muse, mutect2, varscan2
- TMEM87A | c.175_177del p.L59del | In Frame Del (DEL) | VAF 9/57 reads (16%) | called by mutect2, pindel, varscan2
- TRAV8-6 | c.37T>A p.F13I | Missense Mutation (SNP) | VAF 128/238 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- ZNF536 | c.2783del p.S928Ifs*3 | Frame Shift Del (DEL) | VAF 63/261 reads (24%) | called by mutect2, pindel, varscan2
- ZNF658 | c.2006A>G p.Y669C | Missense Mutation (SNP) | VAF 52/219 reads (24%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- ABI1 | c.621A>G p.P207= | Silent (SNP) | VAF 119/168 reads (71%) | catalogued as COSV61019108; called by muse, mutect2, varscan2
- ALG11 | c.705C>A p.I235= | Silent (SNP) | VAF 37/210 reads (18%) | catalogued as rs766400927, COSV101584372; called by muse, mutect2, varscan2
- AMOTL2 | c.91C>T p.L31= | Silent (SNP) | VAF 25/48 reads (52%) | catalogued as COSV51440307; called by muse, mutect2, varscan2
- ANGPT1 | c.396C>A p.T132= | Silent (SNP) | VAF 95/150 reads (63%) | catalogued as rs749711766; called by muse, mutect2, varscan2
- ASH1L | c.8859G>A p.R2953= (on ENST00000368346 / NM_001366177.2; = p.R2948= on NM_018489.3) | Silent (SNP) | VAF 37/176 reads (21%) | catalogued as COSV64211764; called by muse, mutect2, varscan2
- ATP8B3 | c.948C>T p.F316= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as rs1216398524, COSV59541639; called by muse, mutect2, varscan2
- CD247 | c.480C>T p.A160= (on ENST00000362089 / NM_198053.3; = p.A159= on NM_000734.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/165 reads (17%) | catalogued as COSV54822282; called by muse, mutect2, varscan2
- CFL2 | c.9T>G p.S3= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV53312168; called by muse, mutect2, varscan2
- CIZ1 | c.1629C>T p.G543= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as rs551659002, COSV52973559; called by muse, mutect2, varscan2
- CNTNAP5 | c.2400T>A p.S800= | Silent (SNP) | VAF 39/85 reads (46%) | catalogued as COSV70502062; called by muse, mutect2, varscan2
- COL4A6 | c.4890C>A p.A1630= | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as COSV100564399, COSV57873657; called by muse, varscan2
- CSMD1 | c.5160C>T p.S1720= (on ENST00000520002; = p.S1719= on NM_033225.6) | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs983857657, COSV100151822; called by muse, mutect2, varscan2
- DDB1 | c.1896C>A p.G632= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV57104801; called by muse, mutect2
- DENND2C | c.336A>C p.S112= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as COSV67923295; called by muse, mutect2, varscan2
- DMBT1 | c.834C>A p.G278= | Silent (SNP) | VAF 96/413 reads (23%) | catalogued as COSV57553750; called by muse, mutect2, varscan2
- DNAH11 | c.591G>A p.K197= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV60971424; called by muse, mutect2
- EPS8L2 | c.52C>T p.L18= | Silent (SNP) | VAF 29/37 reads (78%) | catalogued as rs781675943, COSV59349527; called by muse, mutect2, varscan2
- ETV3L | c.135C>T p.I45= | Silent (SNP) | VAF 38/72 reads (53%) | catalogued as COSV71901171; called by muse, mutect2, varscan2
- EXOC1 | c.753G>A p.Q251= | Silent (SNP) | VAF 26/72 reads (36%) | catalogued as COSV62121410; called by muse, mutect2, varscan2
- FAM181B | c.108C>T p.C36= | Silent (SNP) | VAF 7/11 reads (64%) | catalogued as rs1323853918, COSV61300914; called by muse, mutect2, varscan2
- FOXP2 | c.525G>A p.Q175= | Silent (SNP) | VAF 12/22 reads (55%) | catalogued as rs778496902, COSV100647160; called by muse, mutect2, varscan2
- GALNT17 | c.1038C>A p.G346= | Silent (SNP) | VAF 26/162 reads (16%) | catalogued as COSV61180570; called by muse, mutect2, varscan2
- GMEB2 | c.321G>A p.K107= | Silent (SNP) | VAF 146/282 reads (52%) | catalogued as COSV56608731; called by muse, mutect2, varscan2
- GRM1 | c.504C>T p.A168= | Silent (SNP) | VAF 36/134 reads (27%) | catalogued as COSV51230372; called by muse, mutect2, varscan2
- GRM8 | c.315G>A p.T105= | Silent (SNP) | VAF 21/43 reads (49%) | catalogued as rs764035146, COSV58853792, COSV58878075; called by muse, mutect2, varscan2
- HAPLN2 | c.117C>T p.P39= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs1397197865, COSV54816086, COSV54816310; called by muse, mutect2, varscan2
- HJV | c.279C>T p.T93= | Silent (SNP) | VAF 45/107 reads (42%) | catalogued as COSV60952830; called by muse, mutect2, varscan2
- HSPA12A | c.1470G>T p.L490= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV65023424; called by muse, mutect2, varscan2
- IQGAP3 | c.1695C>T p.Y565= | Silent (SNP) | VAF 25/44 reads (57%) | catalogued as COSV63253583; called by muse, mutect2, varscan2
- IRS2 | c.1605C>T p.G535= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as rs1420722557, COSV101019287; called by mutect2, varscan2
- KCNH7 | c.666C>A p.P222= | Silent (SNP) | VAF 19/89 reads (21%) | catalogued as COSV100037873, COSV59793298; called by muse, mutect2, varscan2
- KCTD7 | c.459T>A p.T153= (on ENST00000275532; = p.L167M on NM_153033.5) | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as COSV51877261; called by muse, mutect2, varscan2
- KIF21A | c.1857G>A p.E619= (on ENST00000361418 / NM_001378440.1; = p.E606= on NM_017641.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as rs1360683675, COSV62775865; called by muse, mutect2
- KIF21B | c.3606C>A p.G1202= | Silent (SNP) | VAF 39/132 reads (30%) | catalogued as COSV59763143; called by muse, mutect2, varscan2
- KIR2DS4 | c.336A>G p.S112= | Silent (SNP) | VAF 263/507 reads (52%) | called by muse, mutect2, varscan2
- LGSN | c.1278C>T p.A426= | Silent (SNP) | VAF 14/280 reads (5%) | catalogued as rs572903370, COSV65727079; called by muse, mutect2
- LMTK3 | c.4284G>T p.P1428= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as rs201324765, COSV54315774; called by mutect2, varscan2
- LRP1B | c.12786T>C p.T4262= | Silent (SNP) | VAF 46/104 reads (44%) | catalogued as rs771900184, COSV67256177; called by muse, mutect2, varscan2
- MMP9 | c.1722G>A p.R574= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV63434345; called by muse, mutect2, varscan2
- MRTFA | c.1791C>G p.L597= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV62932206, COSV62935408; called by muse, mutect2, varscan2
- MYBL1 | c.924T>G p.S308= | Silent (SNP) | VAF 32/63 reads (51%) | catalogued as COSV72919137; called by muse, mutect2, varscan2
- MYH2 | c.5571T>G p.T1857= | Silent (SNP) | VAF 43/113 reads (38%) | catalogued as COSV55444765; called by muse, mutect2, varscan2
- NOL4 | c.405T>C p.T135= | Silent (SNP) | VAF 29/41 reads (71%) | catalogued as COSV52355993; called by muse, mutect2, varscan2
- NPHP4 | c.3684C>A p.V1228= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV65396740; called by muse, mutect2
- PAIP1 | c.910C>T p.L304= | Silent (SNP) | VAF 196/230 reads (85%) | catalogued as COSV59086911; called by muse, mutect2, varscan2
- PAPOLB | c.921C>A p.P307= | Silent (SNP) | VAF 23/161 reads (14%) | catalogued as COSV68202742; called by muse, mutect2, varscan2
- PCDHGA8 | c.870G>A p.P290= | Silent (SNP) | VAF 56/101 reads (55%) | catalogued as rs370409157; called by muse, mutect2, varscan2
- PLEKHG4B | c.1503G>A p.L501= (on ENST00000283426; = p.L857= on NM_052909.5) | Silent (SNP) | VAF 55/83 reads (66%) | catalogued as COSV52048848, COSV52052296; called by muse, mutect2, varscan2
- PRDM2 | c.81G>A p.P27= | Silent (SNP) | VAF 47/158 reads (30%) | catalogued as rs758175722, COSV52446529; called by muse, mutect2, varscan2
- RAX | c.435G>A p.T145= | Silent (SNP) | VAF 34/73 reads (47%) | catalogued as COSV56874347; called by muse, mutect2, varscan2
- RHOBTB2 | c.489C>A p.I163= | Silent (SNP) | VAF 14/111 reads (13%) | catalogued as COSV99311168; called by muse, mutect2, varscan2
- RIPK1 | c.318C>T p.A106= | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as rs762078179, COSV52530889; called by muse, mutect2, varscan2
- SEC24D | c.2761C>T p.L921= | Silent (SNP) | VAF 31/71 reads (44%) | catalogued as COSV54883154; called by muse, mutect2, varscan2
- SIRPB2 | c.1026G>A p.E342= | Silent (SNP) | VAF 50/132 reads (38%) | catalogued as COSV63124816; called by muse, mutect2, varscan2
- SLC17A7 | c.900G>A p.T300= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as rs1196814117, COSV104380014, COSV55548976; called by muse, mutect2, varscan2
- SLC27A6 | c.462A>G p.R154= | Silent (SNP) | VAF 15/18 reads (83%) | catalogued as COSV52485919; called by muse, mutect2, varscan2
- SLC7A1 | c.297C>T p.L99= | Silent (SNP) | VAF 10/77 reads (13%) | catalogued as COSV66331348; called by muse, mutect2, varscan2
- SULF1 | c.2058G>A p.E686= | Silent (SNP) | VAF 43/155 reads (28%) | catalogued as COSV52689000; called by muse, mutect2, varscan2
- TBC1D8B | c.993C>T p.S331= | Silent (SNP) | VAF 29/77 reads (38%) | catalogued as rs963082189, COSV52181970; called by muse, mutect2, varscan2
- TMEM43 | c.657T>A p.I219= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as COSV60146783; called by muse, mutect2, varscan2
- TRAPPC9 | c.2037G>A p.P679= | Silent (SNP) | VAF 23/123 reads (19%) | catalogued as rs371880751; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- VPS53 | c.411C>T p.H137= (on ENST00000571805 / NM_001366253.2; = p.H108= on NM_018289.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/80 reads (20%) | catalogued as rs765870836, COSV52130943; called by muse, mutect2, varscan2
- XKR3 | c.708C>T p.F236= | Silent (SNP) | VAF 17/54 reads (31%) | called by muse, mutect2, varscan2
- ZNF699 | c.979A>C p.R327= | Silent (SNP) | VAF 65/124 reads (52%) | catalogued as COSV58026556; called by muse, mutect2, varscan2
- ZNF76 | c.1641C>A p.I547= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV57354893; called by muse, mutect2, varscan2
- ZNF781 | c.435G>A p.T145= | Silent (SNP) | VAF 38/149 reads (26%) | catalogued as rs893781530, COSV62201889; called by muse, mutect2, varscan2
- ZSCAN18 | c.861C>T p.S287= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as rs1234683479, COSV53729369; called by muse, mutect2, varscan2
- AC024598.1 | c.1130-939A>C | Intron (SNP) | VAF 22/47 reads (47%) | catalogued as COSV60824563; called by muse, mutect2, varscan2
- CHL1 | c.679+922A>C | Intron (SNP) | VAF 17/64 reads (27%) | catalogued as COSV56587897, COSV56589581; called by muse, mutect2, varscan2
- HLA-DRB9 | n.190G>A | RNA (SNP) | VAF 69/198 reads (35%) | catalogued as rs769848815; called by muse, mutect2, varscan2
- IL17C | c.*1C>T | 3'UTR (SNP) | VAF 52/104 reads (50%) | catalogued as COSV99733360; called by muse, mutect2, varscan2
- PARVB | c.713-121G>A | Intron (SNP) | VAF 25/101 reads (25%) | called by muse, mutect2, varscan2
- POM121 | chr7:72950086 C>T | 3'Flank (SNP) | VAF 13/80 reads (16%) | catalogued as rs782775551, COSV99988905; called by muse, mutect2, varscan2
- TMPRSS11F | c.1015+1902G>A | Intron (SNP) | VAF 19/124 reads (15%) | catalogued as rs372094655, COSV62464490; called by muse, mutect2, varscan2
